HCMI case HCM-BROD-0759-C15 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Esophagus. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/02187bfb-54f4-4bed-a056-06c9f10e3335

Demographics
Sex at birth: male; Ethnicity: not hispanic or latino; Year of birth: 1948; Vital status: Alive.

Diagnoses (2)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C15.9; Tissue or organ of origin: Esophagus, NOS; Classification of tumor: primary; Age at diagnosis: 70.5 years (25,738 days); AJCC staging edition: 8th; AJCC pathologic T: T4; AJCC pathologic N: N1; AJCC pathologic M: M1; Tumor grade: GX; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: no; Prior treatment: Yes; Sites of involvement: Liver.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Ramucirumab; Treatment intent type: Neoadjuvant; Days to treatment start: 165 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil + Leucovorin Calcium + Oxaliplatin; Treatment intent type: Neoadjuvant; Regimen or line of therapy: FOLFOX; Days to treatment start: 222 days.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Nivolumab; Treatment intent type: Neoadjuvant; Days to treatment start: 250 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 544 days (1.5 years); Days to treatment end: 706 days (1.9 years).
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Ramucirumab; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 544 days (1.5 years); Days to treatment end: 706 days (1.9 years).
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil + Leucovorin Calcium + Oxaliplatin; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Regimen or line of therapy: FOLFOX; Days to treatment start: 733 days (2.0 years); Days to treatment end: 775 days (2.1 years).
   Recorded as not given: adjuvant Immunotherapy (Including Vaccines), for residual disease; neoadjuvant Radiation Therapy, NOS; adjuvant Radiation Therapy, NOS, for residual disease; Surgery, NOS, for initial diagnosis.
2. Adenocarcinoma, metastatic, NOS: ICD-O-3 morphology code: 8140/6; ICD-10 code: C79.8; Tissue or organ of origin: Esophagus, NOS; Site of resection or biopsy: Pelvis, NOS; Classification of tumor: metastasis; Age at diagnosis: 70.5 years (25,738 days); Gastric esophageal junction involvement: No.

Follow-up (2 entries)
- Days to follow up: 0 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Liver; Days to progression: 0 days.
- Days to follow up: 775 days (2.1 years); Disease response: Progressive Disease; Progression or recurrence: Yes.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Comorbidities: Barrett's Esophagus; Risk factors: Barrett's Esophagus.
- Timepoint category: Initial Diagnosis; BMI: 38; Comorbidities: Barrett's Esophagus; Risk factors: Barrett's Esophagus.

Exposures
- Tobacco smoking status: Current Reformed Smoker, Duration Not Specified; Pack years smoked: 8; Tobacco smoking quit year: 1971; Alcohol intensity: Occasional Drinker; Alcohol days per week: 7.

Family history
- Relative with cancer history: yes; Relationship type: First Degree Relative, NOS; Relationship primary diagnosis: Cancer.

Biospecimens (1 sample)
- Sample HCM-BROD-0759-C15-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 6.
